Somatic mutation profile of tumor specimen 0DRU3U from CCDI case PBCGWB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 15.5 years (5,662 days).
Specimen 0DRU3U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 795844cf-3161-441d-9e50-3482bde95222.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRU3O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ea3210b-fe0f-4229-8a9a-cc25966f8763

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 3, Silent 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXO16 | c.223C>G p.R75G | Missense Mutation (SNP) | VAF 263/846 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as rs777366526, COSV60775521; called by muse, mutect2, varscan2
- SMARCA4 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 231/369 reads (63%) | catalogued as COSV60806537; called by muse, mutect2, varscan2
- TMEM63A | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 255/842 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.804); catalogued as rs368334549, COSV100834442; called by muse, mutect2, varscan2
- ADAM12 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 123/429 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BNIP3 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 243/844 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C1orf94 | c.1447G>A p.G483S (on ENST00000488417 / NM_001134734.2; = p.G293S on NM_032884.5) | Missense Mutation (SNP) | VAF 99/329 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- NAV2 | c.2612G>A p.G871E (on ENST00000396087 / NM_001244963.2; = p.G848E on NM_145117.5) | Missense Mutation (SNP) | VAF 99/324 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- SLITRK1 | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 162/635 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUT4 | c.4568T>C p.I1523T | Missense Mutation (SNP) | VAF 147/426 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- ZC4H2 | c.264C>G p.N88K | Missense Mutation (SNP) | VAF 233/879 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- KRT37 | c.267C>T p.I89= | Silent (SNP) | VAF 142/886 reads (16%) | catalogued as rs140730413; called by muse, mutect2, varscan2
- SCN9A | c.5097C>G p.G1699= (on ENST00000303354; = p.G1688= on NM_002977.3) | Silent (SNP) | VAF 276/919 reads (30%) | called by muse, mutect2, varscan2
- EMC4 | c.516+21A>T | Intron (SNP) | VAF 164/466 reads (35%) | called by mutect2, varscan2
- GNL1 | c.-80C>A | 5'UTR (SNP) | VAF 39/110 reads (35%) | called by muse, mutect2, varscan2
- MAP7 | c.67+24282G>C | Intron (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- NOX4 | c.1516-48G>A | Intron (SNP) | VAF 45/152 reads (30%) | catalogued as rs12798436; called by muse, mutect2, varscan2
